Gene-level copy-number profile of tumor specimen C3L-00935-01 from CPTAC case C3L-00935, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Tumor grade: G1; Age at diagnosis: 74.8 years (27,315 days).
Specimen C3L-00935-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7071a528-f8a2-4dca-bd25-7750bd5b2a63.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00935-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/bfe4ad37-5b3b-4ecc-97a7-bfe669fa4447

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 849; copy number 2: 14,664; copy number 3: 23,456; copy number 4: 12,813; copy number 5: 4,923; copy number 6: 592; copy number 7: 108; copy number 8: 248; copy number 9: 145; copy number 10: 24; copy number 11: 5; copy number 12: 145; copy number 13: 34; copy number 14: 232; copy number 17: 18; copy number 24: 105; copy number 34: 18; copy number 57: 10.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,092 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–150,697,154, 258 genes, copy number 7–14 (broad region; genes not listed).
- chr6:104,687,241–113,224,072, 168 genes, copy number 7–12 (broad region; genes not listed).
- chr7:67,627,831–69,597,493, 21 genes, copy number 10: MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231, AC104688.1, RNU6-832P, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66.
- chr8:35,862,123–36,936,125, 15 genes, copy number 8: AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8.
- chr9:66,721,158–75,028,423, 120 genes, copy number 9–12 (broad region; genes not listed).
- chr10:74,151,202–86,366,795, 183 genes, copy number 7–14 (broad region; genes not listed).
- chr13:108,207,439–113,845,744, 106 genes, copy number 17–24 (within-gene range 3–24) (broad region; genes not listed).
- chr15:93,035,273–98,964,530, 91 genes, copy number 12–57 (within-gene range 2–57) (broad region; genes not listed).
- chr19:27,638,483–27,794,005, 4 genes, copy number 8 (within-gene range 6–8): ERVK-28, AC112702.1, LINC00662, AC006504.1.
- chr20:43,652,523–46,864,104, 126 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 849. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
